Gene-level copy-number profile of tumor specimen TARGET-10-PATPWF-03A from TARGET case TARGET-10-PATPWF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (661 days).
Specimen TARGET-10-PATPWF-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.ea4d2e4e-ecfa-584b-92b8-e17fabb316cc.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATPWF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 402 have no estimate.
https://portal.gdc.cancer.gov/files/0f00ac07-88b8-44d8-af57-1388727fa665

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 90; copy number 1: 3,800; copy number 2: 55,699; copy number 3: 625; copy number 4: 7.

Homozygous deletions (total copy number 0; autosomes only): 90 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:166,474,745–166,481,565, 1 gene: FMO7P.
- chr6:112,087,591–112,102,790, 1 gene (within-gene range 0–1): FAM229B.
- chr7:38,273,587–38,378,804, 19 genes: TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr7:142,440,883–142,793,368, 53 genes: TRBV12-2, TRBV6-5, TRBV7-4, TRBV5-4, TRBV6-6, TRBV7-5, TRBV5-5, TRBV6-7, TRBV7-6, TRBV5-6, TRBV6-8, TRBV7-7, TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr14:22,197,446–22,482,959, 1 gene (within-gene range 0–1): AC244502.1.
- chr14:22,304,054–22,439,015, 8 genes: TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,407. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
